CCDI case PBBWAV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/b91a1faa-3652-4940-9cbb-648a62c9fe58

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 5.1 years (1,864 days).

Biospecimens (3 samples)
- Sample 0DIW65: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW71: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW7T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
